Somatic mutation profile of tumor specimen ALCH-AEL4-TTP1-A (aliquot ALCH-AEL4-TTP1-A-2-0-D-A596-36) from ALCHEMIST case ALCH-AEL4, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 68.1 years (24,862 days).
Specimen ALCH-AEL4-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9bbbad0b-ccea-4c08-b255-11d667945009.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEL4-NB1-A (Blood Derived Normal), aliquot ALCH-AEL4-NB1-A-1-0-D-A596-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f4336fd-93c9-403c-be59-60a91c53d1d3

The open-access MAF lists 65 somatic variants for this specimen: 41 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 19, Frame Shift Del 3, Intron 2, 3'UTR 1, Splice Region 1, Splice Site 1, 5'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATAD2 | c.1804G>C p.E602Q | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV54884237; called by muse, mutect2
- ATP6V1D | c.82A>G p.T28A | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as rs760322362; called by muse, mutect2, varscan2
- DLGAP4 | c.1555G>A p.A519T | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs1317471180; called by muse, mutect2, varscan2
- DZIP1 | c.2437G>A p.E813K (on ENST00000347108; = p.E794K on NM_014934.5) | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated (0.81); PolyPhen benign (0.026); catalogued as rs769638971; called by muse, mutect2, varscan2
- FAT1 | c.13546C>T p.H4516Y | Missense Mutation (SNP) | VAF 17/143 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101499352, COSV101499415; called by muse, mutect2, varscan2
- LAMA3 | c.8592C>G p.I2864M (on ENST00000313654 / NM_198129.4; = p.I1255M on NM_000227.6) | Missense Mutation (SNP) | VAF 32/564 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV52535196; called by muse, mutect2
- MDM2 | c.959C>A p.P320H | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50701289; called by muse, mutect2, varscan2
- PSMD7 | c.79G>A p.G27S | Missense Mutation (SNP) | VAF 20/307 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs1433247617, COSV54697800; called by muse, mutect2
- PXDNL | c.3964C>G p.Q1322E | Missense Mutation (SNP) | VAF 11/177 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62499114; called by muse, mutect2
- TP53 | c.370del p.C124Afs*46 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as COSV52680549, COSV52752618; called by mutect2, pindel, varscan2
- ADRB1 | c.463G>C p.D155H | Missense Mutation (SNP) | VAF 6/114 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARHGEF40 | c.3137A>G p.E1046G | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- CACNA1C | c.373C>G p.P125A | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2
- CD160 | c.334T>C p.C112R | Missense Mutation (SNP) | VAF 24/159 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CNDP2 | c.925_929del p.W309Vfs*41 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | called by mutect2, pindel, varscan2
- EFCAB6 | c.1934A>T p.D645V | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2
- EGFR | c.829A>G p.M277V | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- EGFR | c.830T>A p.M277K | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- GRIK3 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, varscan2
- GYPA | c.436+2T>C p.X146_splice | Splice Site (SNP) | VAF 18/356 reads (5%) | called by muse, mutect2
- HSP90AA1 | c.738A>C p.E246D | Missense Mutation (SNP) | VAF 43/344 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- JRK | c.869A>T p.E290V | Missense Mutation (SNP) | VAF 11/183 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2
- KCND1 | c.1866G>T p.R622S | Missense Mutation (SNP) | VAF 5/37 reads (14%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- LVRN | c.1807C>G p.L603V | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT tolerated (0.33); PolyPhen benign (0.136); called by muse, mutect2
- MAP1B | c.1247G>C p.G416A | Missense Mutation (SNP) | VAF 4/92 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MMEL1 | c.1241del p.R414Nfs*7 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | called by mutect2, pindel, varscan2
- MMP9 | c.1109G>C p.R370P | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2
- MSH3 | c.2665G>C p.E889Q | Missense Mutation (SNP) | VAF 9/236 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.083); called by muse, mutect2
- NDC80 | c.1685G>T p.R562L | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- NEB | c.2214T>C p.H738= | Splice Region (SNP) | VAF 9/144 reads (6%) | called by muse, mutect2
- PIGV | c.274C>G p.P92A | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- POLA1 | c.3569A>T p.Q1190L | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.705); called by muse, mutect2
- PPL | c.1074G>C p.E358D | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.978); called by muse, varscan2
- PRDM2 | c.4142A>G p.N1381S | Missense Mutation (SNP) | VAF 102/355 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PSMA8 | c.470C>G p.P157R | Missense Mutation (SNP) | VAF 17/136 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAB33A | c.114A>C p.K38N | Missense Mutation (SNP) | VAF 19/147 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RASAL3 | c.974G>A p.G325D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.368); called by muse, varscan2
- RMC1 | c.1801A>C p.K601Q | Missense Mutation (SNP) | VAF 40/337 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP40 | c.908G>C p.G303A | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- WBP2NL | c.833C>T p.A278V | Missense Mutation (SNP) | VAF 7/114 reads (6%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.003); called by muse, mutect2
- ZNF106 | c.1876G>C p.E626Q | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- CADM3 | c.1005G>T p.G335= (on ENST00000368125 / NM_001127173.3; = p.G369= on NM_021189.5) | Silent (SNP) | VAF 16/222 reads (7%) | catalogued as rs759464369, COSV63676173; called by muse, mutect2
- CDH18 | c.312C>T p.D104= | Silent (SNP) | VAF 107/304 reads (35%) | catalogued as rs368155280, COSV56951957; called by muse, mutect2, varscan2
- CHI3L2 | c.177C>G p.L59= | Silent (SNP) | VAF 32/368 reads (9%) | catalogued as COSV63874340; called by muse, mutect2
- ENPEP | c.1926G>A p.A642= | Silent (SNP) | VAF 23/110 reads (21%) | catalogued as rs757912646, COSV99487955; called by muse, mutect2, varscan2
- GCC1 | c.207C>G p.L69= | Silent (SNP) | VAF 6/69 reads (9%) | catalogued as rs1395265515, COSV50002338; called by muse, mutect2
- GPR149 | c.2094G>A p.Q698= | Silent (SNP) | VAF 12/84 reads (14%) | called by muse, mutect2, varscan2
- H3C2 | c.186G>A p.L62= | Silent (SNP) | VAF 15/177 reads (8%) | catalogued as rs149213082, COSV52518058; called by muse, mutect2
- LLCFC1 | c.333G>A p.T111= (on ENST00000458732; = p.T80= on NM_178829.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/230 reads (4%) | catalogued as rs1387721230, COSV62334034; called by muse, mutect2
- NAGS | c.1380G>A p.L460= | Silent (SNP) | VAF 13/43 reads (30%) | catalogued as rs1428233890; called by muse, mutect2, varscan2
- NEO1 | c.513G>A p.L171= | Silent (SNP) | VAF 11/217 reads (5%) | called by muse, mutect2
- PCDH15 | c.1803G>T p.V601= | Silent (SNP) | VAF 19/268 reads (7%) | called by muse, mutect2
- PPFIA2 | c.1044C>A p.L348= | Silent (SNP) | VAF 20/217 reads (9%) | called by muse, mutect2
- SCN4A | c.2520C>G p.L840= | Silent (SNP) | VAF 5/44 reads (11%) | called by muse, mutect2, varscan2
- STXBP5 | c.489A>T p.R163= | Silent (SNP) | VAF 20/382 reads (5%) | called by muse, mutect2
- SULT6B1 | c.339G>A p.R113= (on ENST00000535679 / NM_001367551.1; = p.R75= on NM_001032377.2) | Silent (SNP) | VAF 18/128 reads (14%) | catalogued as rs774148547; called by muse, varscan2
- SYNE2 | c.3000G>A p.R1000= | Silent (SNP) | VAF 69/349 reads (20%) | called by muse, mutect2, varscan2
- TRAC | c.396G>A p.L132= | Silent (SNP) | VAF 22/281 reads (8%) | called by muse, mutect2
- TUBGCP4 | c.241T>C p.L81= | Silent (SNP) | VAF 23/355 reads (6%) | called by muse, mutect2
- WASHC5 | c.3379C>T p.L1127= | Silent (SNP) | VAF 22/368 reads (6%) | called by muse, mutect2
- AP000769.5 | chr11:65499266 G>A | 5'Flank (SNP) | VAF 24/306 reads (8%) | called by muse, mutect2
- NIBAN1 | c.*48A>T | 3'UTR (SNP) | VAF 42/224 reads (19%) | catalogued as COSV100836628; called by muse, mutect2
- PLB1 | c.937-336C>A | Intron (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- RRP12 | c.-138+6560G>C | Intron (SNP) | VAF 14/197 reads (7%) | called by muse, mutect2
- ZDHHC1 | c.-2C>G | 5'UTR (SNP) | VAF 64/281 reads (23%) | catalogued as rs1291278297; called by muse, mutect2, varscan2
